Somatic mutation profile of tumor specimen a8853382-b726-4ce8-98d5-ca89df (aliquot a8853382-b726-4ce8-98d5-ca89df_D6) from CPTAC case 04OV011, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen a8853382-b726-4ce8-98d5-ca89df: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed1a9241-d37e-4b4b-9873-25f4ad57b1a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c36b85ce-4c29-4bc4-9ae4-6fa57b (Blood Derived Normal), aliquot c36b85ce-4c29-4bc4-9ae4-6fa57b_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4256530-d855-4303-b4a2-01bd927b3240

The open-access MAF lists 81 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 17, Splice Site 4, Frame Shift Del 4, Intron 2, 3'UTR 2, Translation Start Site 1, Splice Region 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 578/608 reads (95%) | hotspot (GDC flag); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.3086G>A p.R1029H | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1203849682, COSV54356315; called by muse, mutect2, varscan2
- ARFGEF1 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99031278; called by muse, mutect2, varscan2
- COL22A1 | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57358336; called by muse, mutect2
- GLIS2 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 256/451 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs780851672, COSV99267645; called by muse, mutect2, varscan2
- H1-3 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs916897940; called by muse, mutect2, varscan2
- ICE2 | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs890249199, COSV55030991; called by muse, mutect2, varscan2
- IFIT1B | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1356087646; called by muse, mutect2, varscan2
- IRF2BP1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 160/290 reads (55%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as rs763014256; called by muse, mutect2, varscan2
- IZUMO1 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365922856, COSV55802782; called by muse, mutect2, varscan2
- MALRD1 | c.6236G>T p.G2079V | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1370915543; called by muse, mutect2, varscan2
- MYH4 | c.4021C>T p.R1341C | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs765219970; called by muse, mutect2, varscan2
- NBPF14 | c.2615A>G p.E872G | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1430421905; called by muse, varscan2
- PDCD11 | c.1274G>C p.S425T | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs768975390; called by muse, mutect2, varscan2
- SLC16A14 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54621672; called by muse, mutect2, varscan2
- SVIL | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as rs1341237200; called by muse, mutect2, varscan2
- TENM2 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1472652448, COSV72853353; called by muse, mutect2, varscan2
- ADAMTS9 | c.1712A>C p.H571P | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.796T>A p.F266I | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AR | c.2592_2596del p.D865Rfs*14 | Frame Shift Del (DEL) | VAF 104/133 reads (78%) | called by mutect2, pindel, varscan2
- AR | c.2613_2620del p.R872Afs*6 | Frame Shift Del (DEL) | VAF 98/121 reads (81%) | called by mutect2, pindel, varscan2
- ASF1A | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- B3GALT2 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CACNA1E | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 180/392 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRISPLD1 | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CSE1L | c.567+1G>T p.X189_splice | Splice Site (SNP) | VAF 31/74 reads (42%) | called by mutect2, varscan2
- CSMD1 | c.8467A>G p.S2823G (on ENST00000520002; = p.S2822G on NM_033225.6) | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CYP3A4 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by mutect2, varscan2
- DCLRE1B | c.356-1G>C p.X119_splice | Splice Site (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- DIS3L2 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFNA1 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FAT1 | c.3336_3340del p.D1113Gfs*16 | Frame Shift Del (DEL) | VAF 51/117 reads (44%) | called by mutect2, pindel, varscan2
- FMO1 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GLIPR1 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 214/329 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- HARS1 | c.-3_2delinsCCCC | Translation Start Site (DEL) | VAF 25/69 reads (36%) | called by pindel, varscan2*
- JARID2 | c.1586A>C p.Q529P | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by mutect2, varscan2
- LRRC53 | c.1420+1G>T p.X474_splice | Splice Site (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- MAP4K5 | c.2181T>A p.D727E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAP6 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, varscan2
- MYO1F | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 157/497 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- NDUFS8 | c.372+5G>A | Splice Region (SNP) | VAF 102/311 reads (33%) | called by muse, mutect2, varscan2
- PALB2 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2
- PAPSS1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PARP14 | c.3217A>G p.M1073V | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGEF1A | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF169 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SLC9A3R2 | c.862A>T p.S288C | Missense Mutation (SNP) | VAF 122/207 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- SPATA31D1 | c.1373T>A p.I458N | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- TAPT1 | c.321A>T p.E107D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TCP1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TDG | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 72/119 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TMEM199 | c.105G>C p.E35D | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- TMPRSS11A | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 116/220 reads (53%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRANK1 | c.144del p.Y48* | Frame Shift Del (DEL) | VAF 28/59 reads (47%) | called by mutect2, pindel, varscan2
- TRPM8 | c.118-2A>G p.X40_splice | Splice Site (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- U2AF2 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- UBA3 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZBTB12 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE27 | c.243C>G p.N81K | Missense Mutation (SNP) | VAF 133/448 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CHD6 | c.3285G>A p.A1095= | Silent (SNP) | VAF 70/289 reads (24%) | catalogued as rs370618644; called by muse, mutect2, varscan2
- COMP | c.2154G>T p.R718= | Silent (SNP) | VAF 222/766 reads (29%) | catalogued as rs780066431, COSV99721537; called by mutect2, varscan2
- FBXO41 | c.606G>A p.L202= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as COSV54583184; called by muse, mutect2, varscan2
- FHAD1 | c.1266C>A p.I422= | Silent (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- HTRA4 | c.513C>T p.A171= | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as COSV56761225; called by muse, mutect2, varscan2
- KCTD8 | c.1245C>T p.T415= | Silent (SNP) | VAF 75/174 reads (43%) | catalogued as rs757459146; called by muse, mutect2, varscan2
- MEGF11 | c.621A>T p.A207= | Silent (SNP) | VAF 41/132 reads (31%) | called by muse, mutect2, varscan2
- MGAM2 | c.2796G>T p.G932= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs747466327; called by muse, mutect2, varscan2
- MRPS15 | c.219C>G p.L73= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- MYH11 | c.3429C>T p.D1143= | Silent (SNP) | VAF 184/530 reads (35%) | called by muse, mutect2, varscan2
- OR2M3 | c.330T>G p.S110= | Silent (SNP) | VAF 156/329 reads (47%) | called by muse, mutect2, varscan2
- PTPRG | c.3864T>C p.S1288= | Silent (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- PYROXD2 | c.291G>A p.Q97= | Silent (SNP) | VAF 62/176 reads (35%) | called by muse, mutect2, varscan2
- SLC13A3 | c.408G>A p.S136= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs914602203; called by muse, mutect2, varscan2
- TACR3 | c.267C>A p.S89= | Silent (SNP) | VAF 87/186 reads (47%) | called by mutect2, varscan2
- USP34 | c.5346A>G p.V1782= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as rs781033174; called by muse, mutect2, varscan2
- XPO4 | c.1150C>A p.R384= | Silent (SNP) | VAF 43/61 reads (70%) | catalogued as COSV55007182, COSV55011354; called by muse, mutect2, varscan2
- CASP10 | c.1415+8189_1415+8194del | Intron (DEL) | VAF 74/278 reads (27%) | called by mutect2, pindel, varscan2
- CCP110 | c.*29G>T | 3'UTR (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- CFAP46 | c.7117+586G>A | Intron (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
- MIR365B | chr17:31571337 T>A | 5'Flank (SNP) | VAF 56/124 reads (45%) | called by muse, mutect2, varscan2
- ZNF99 | c.*700G>T | 3'UTR (SNP) | VAF 32/123 reads (26%) | called by mutect2, varscan2
